Gene-level copy-number profile of tumor specimen AP-9D3B-DL from APOLLO case AP-9D3B, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2.
Specimen AP-9D3B-DL: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2216854e-968e-4836-b2b3-8e618425937d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-9D3B-7U (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/ea32f8cd-0776-4a93-825d-cbceb59367da

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 1,370; copy number 2: 13,315; copy number 3: 17,303; copy number 4: 14,520; copy number 5: 8,106; copy number 6: 2,412; copy number 7: 534; copy number 8: 663; copy number 9: 73; copy number 11: 27; copy number 14: 47.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr9:40,883,634–40,929,092, 2 genes: AL353626.2, MIR1299.
- chr10:38,783,004–38,783,108, 1 gene: AL590623.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,344 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,541,501–147,626,216, 2 genes, copy number 8: BCL9, AC242628.1.
- chr1:154,155,304–155,331,114, 73 genes, copy number 7 (broad region; genes not listed).
- chr1:159,780,932–161,230,746, 82 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr1:234,565,298–234,980,804, 17 genes, copy number 7: AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3.
- chr5:14,143,342–14,532,128, 2 genes, copy number 8 (within-gene range 6–8): TRIO, AC016549.1.
- chr5:36,098,407–37,966,964, 36 genes, copy number 7: LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1.
- chr6:15,243,923–16,766,883, 24 genes, copy number 7: AL136162.1, JARID2, JARID2-AS1, RNU6-522P, RNU6-645P, 5S_rRNA, DTNBP1, AL021978.1, ARPC3P5, LINC02543, AL365265.1, MDH1P2, MYLIP, MIR4639, AL021407.2, AL021407.1, MRPL42P2, RNU6-1114P, Y_RNA, GMPR, AL009031.1, ATXN1, ATXN1-AS1, AL137003.1.
- chr6:33,694,293–33,804,003, 6 genes, copy number 7 (within-gene range 6–7): UQCC2, MIR3934, IP6K3, LEMD2, MLN, AL138889.3.
- chr6:43,722,786–44,307,506, 20 genes, copy number 7 (within-gene range 6–7): AL136131.2, VEGFA, AL136131.3, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B.
- chr6:44,278,734–44,297,698, 1 gene, copy number 7 (within-gene range 6–7): TCTE1.
- chr7:55,019,017–55,211,628, 2 genes, copy number 7: EGFR, EGFR-AS1.
- chr8:64,798,804–69,834,978, 74 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr8:70,103,798–70,669,185, 13 genes, copy number 8: H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P.
- chr8:71,155,454–80,231,232, 120 genes, copy number 7–9 (broad region; genes not listed).
- chr8:80,484,561–83,408,900, 55 genes, copy number 8: AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5, AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2, ZFAND1, CHMP4C, AC132219.1, SNX16, HNRNPA1P36, LINC02235, AC060765.2, LINC02839, HNRNPA1P4, AC060765.1, AC105031.2, AC105031.1, AC090095.1, AC090132.1, AC090132.2, LINC01419.
- chr8:84,162,118–109,691,791, 418 genes, copy number 7–9 (broad region; genes not listed).
- chr8:113,950,886–113,950,998, 1 gene, copy number 8: Y_RNA.
- chr8:114,791,653–131,317,632, 217 genes, copy number 7–9 (broad region; genes not listed).
- chr8:131,712,512–135,456,952, 57 genes, copy number 7: AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1.
- chr8:135,859,369–138,083,657, 7 genes, copy number 8 (within-gene range 6–8): LINC02055, RNU6-144P, ZYXP1, AC110053.1, AC046195.1, AC046195.2, AC079015.1.
- chr12:25,959,029–26,125,037, 2 genes, copy number 7 (within-gene range 5–7): RASSF8, BHLHE41.
- chr12:68,272,443–70,434,292, 55 genes, copy number 9–14: MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4.
- chr12:70,638,073–70,920,738, 1 gene, copy number 11 (within-gene range 3–11): PTPRR.
- chr12:70,906,917–72,728,844, 26 genes, copy number 11: Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1.
- chr17:21,428,263–21,574,517, 1 gene, copy number 8 (within-gene range 2–8): LINC02693.
- chr17:21,532,974–22,606,703, 32 genes, copy number 8 (within-gene range 2–8): AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1, AC233702.4, AC233702.9, KCNJ18, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC131055.2, AC131055.1.

Autosomal genes at a single copy (total copy number 1): 1,370. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
